Surgical pathology report (de-identified scan), TCGA case TCGA-YR-A95A, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-YR-A95A-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Liver

I-) Right lobe and segment IV of liver:

- Moderately differentiated cholangiocarcinoma measuring 7.5 x 4.5 x 3.6cm.
- Intense stromal desmoplasia.
- Presence of tumoral perineural infiltration.
- Resection margin compromised by the neoplasia.

II-) Hepatic hilus tumor:

- Moderately differentiated cholangiocarcinoma.
- Margins are compromised.

ICD O 3
Cholangiocarcinoma 8160/3
Site: Extra-hepatic bile duct
C24.0
JES 6/13/14

Source: NCI Genomic Data Commons file dd25bc09-9420-4ce9-8b90-d4ba3291658f (TCGA-YR-A95A.AB615D8F-E4A3-48A9-86A3-C89861C89A5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).